CCDI case PBBNMC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/89162783-c30e-4fc7-b81f-089bd2e5faab

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (434 days).

Biospecimens (3 samples)
- Sample 0DDKF6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDKF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DDKF8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
